TARGET case TARGET-40-NAAHDB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/c933e4e3-8dde-5a3d-ae41-f479b20dccbd

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Long bones of lower limb and associated joints; Age at diagnosis: 9.8 years (3,577 days); Year of diagnosis: 2007; Days to last follow up: 2,888 days (7.9 years).

Biospecimens (2 samples)
- Sample TARGET-40-NAAHDB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHDB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
